Somatic mutation profile of tumor specimen TCGA-GC-A6I1-01A (aliquot TCGA-GC-A6I1-01A-12D-A31L-08) from TCGA case TCGA-GC-A6I1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-GC-A6I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5db8ebf-4beb-4fb0-8c83-2d8be214357a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GC-A6I1-10A (Blood Derived Normal), aliquot TCGA-GC-A6I1-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76da3517-06c5-4d52-ac27-c8c5616e24bd

The open-access MAF lists 255 somatic variants for this specimen: 176 protein-altering or splice-affecting, 76 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 76, Nonsense Mutation 20, Frame Shift Ins 2, Frame Shift Del 2, RNA 2, Splice Site 2, Splice Region 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15079C>T p.R5027* | Nonsense Mutation (SNP) | VAF 41/110 reads (37%) | catalogued as rs797045659, CM111923, COSV56437167; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 32/73 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs1370542996, COSV66105800; called by muse, mutect2, varscan2
- ABCA7 | c.4008G>A p.W1336* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as CM166821, COSV99566771; called by muse, mutect2, varscan2
- ABCG2 | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as rs776215859, COSV99420373; called by muse, mutect2, varscan2
- ACTR3B | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 32/115 reads (28%) | catalogued as COSV99754668; called by muse, mutect2, varscan2
- ADCY1 | c.1535T>C p.M512T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV52030230, COSV52034000; called by muse, mutect2, varscan2
- AK9 | c.3221dup p.Q1075Afs*22 | Frame Shift Ins (INS) | VAF 19/70 reads (27%) | catalogued as rs1467728410; called by mutect2, pindel, varscan2
- ANKRD17 | c.3715G>C p.D1239H | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58215584; called by muse, mutect2, varscan2
- ANKS1B | c.2426G>A p.R809K (on ENST00000547776 / NM_152788.4; = p.R35K on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs1261340016, COSV60357004, COSV60360483; called by muse, mutect2, varscan2
- ANO7 | c.762G>C p.K254N (on ENST00000274979; = p.K200N on NM_001370694.2) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs758773032, COSV51468339, COSV51472546; called by muse, mutect2, varscan2
- ARHGAP20 | c.878C>G p.P293R | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.303); catalogued as COSV52806827; called by muse, mutect2, varscan2
- ARHGAP29 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53108408; called by muse, mutect2, varscan2
- ASMTL | c.1646G>C p.G549A | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV67242921; called by muse, mutect2, varscan2
- ATP2C2 | c.984C>A p.V328= | Splice Region (SNP) | VAF 54/245 reads (22%) | catalogued as COSV52292910; called by muse, mutect2, varscan2
- AZIN1 | c.980A>G p.K327R | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.151); catalogued as COSV61479258; called by muse, mutect2, varscan2
- BDP1 | c.5234G>C p.R1745T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs772979594, COSV62429023; called by muse, mutect2, varscan2
- BLVRA | c.135-1G>C p.X45_splice | Splice Site (SNP) | VAF 39/160 reads (24%) | catalogued as COSV55512527; called by muse, mutect2, varscan2
- BNIP1 | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV51569987, COSV51570957; called by muse, mutect2, varscan2
- C4orf50 | c.370G>A p.E124K (on ENST00000324058; = p.E1356K on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV60687495; called by muse, mutect2, varscan2
- CA8 | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.928); catalogued as COSV58770421; called by muse, mutect2, varscan2
- CAB39L | c.324G>C p.Q108H | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV61713647; called by muse, mutect2, varscan2
- CABYR | c.1058C>G p.S353C | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV59110202; called by muse, mutect2
- CACNB3 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56397285; called by muse, mutect2, varscan2
- CAT | c.1106A>G p.N369S | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148712764, COSV53810230; called by muse, mutect2, varscan2
- CBFA2T2 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60073102; called by muse, mutect2, varscan2
- CEP20 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.606); catalogued as COSV55383513; called by muse, mutect2, varscan2
- CIT | c.1918G>C p.E640Q | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV99951229; called by muse, mutect2
- CLIP2 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56274626; called by muse, mutect2, varscan2
- CLMN | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1311437965, COSV54179120; called by muse, mutect2, varscan2
- COL6A5 | c.7543C>A p.P2515T (on ENST00000312481; = p.P2511T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as rs983022182, COSV55193936; called by muse, mutect2, varscan2
- CORO1C | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV54594216; called by muse, mutect2, varscan2
- CPEB4 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.49); catalogued as COSV54169721; called by muse, mutect2, varscan2
- CYFIP2 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59028571; called by muse, mutect2, varscan2
- DENND5A | c.2859G>A p.L953= | Splice Region (SNP) | VAF 133/342 reads (39%) | catalogued as COSV60231515; called by muse, mutect2, varscan2
- DEPDC5 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); catalogued as rs886039278, CM134028, COSV56691364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX9 | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV62358263; called by muse, mutect2, varscan2
- DIP2B | c.3989C>T p.S1330L | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV56579057; called by muse, mutect2, varscan2
- DNAJC14 | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54477772; called by muse, mutect2, varscan2
- DOCK7 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51996220, COSV52002182, COSV52011081; called by muse, mutect2, varscan2
- DOK6 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66926540, COSV66938565; called by muse, mutect2
- DRD5 | c.1314C>G p.F438L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58576736; called by muse, mutect2, varscan2
- DVL1 | c.1702C>T p.Q568* (on ENST00000378888 / NM_001330311.2; = p.Q543* on NM_004421.3) | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100229920; called by muse, mutect2, varscan2
- DYM | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.589); catalogued as COSV53980465; called by muse, mutect2, varscan2
- DYNC1H1 | c.4204G>A p.E1402K | Missense Mutation (SNP) | VAF 53/409 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV64134476, COSV64144317; called by muse, mutect2, varscan2
- EBLN2 | c.244A>T p.K82* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99866416; called by muse, mutect2, varscan2
- EGF | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs567044142, COSV54475735, COSV54477086; called by muse, mutect2, varscan2
- ELF3 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.989); catalogued as COSV62837284; called by muse, mutect2, varscan2
- ELF3 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); catalogued as COSV62837294, COSV62838315; called by muse, mutect2, varscan2
- ELF4 | c.480G>C p.E160D | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV57451470, COSV57451884; called by muse, mutect2, varscan2
- EML4 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV59293938; called by muse, mutect2, varscan2
- ENPP6 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs748666536, COSV57065938; called by muse, mutect2, varscan2
- EPX | c.304_306del p.E102del | In Frame Del (DEL) | VAF 18/76 reads (24%) | catalogued as COSV56594980; called by mutect2, pindel, varscan2
- ERCC1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs754051080, COSV50003687; called by muse, mutect2, varscan2
- ESYT1 | c.2273C>G p.S758C | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57271684; called by muse, mutect2, varscan2
- ETS1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60091878; called by muse, mutect2, varscan2
- EYS | c.1063A>G p.M355V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV60976940; called by muse, mutect2, varscan2
- F11 | c.648C>G p.D216E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.025); catalogued as rs1369327019, COSV53004258; called by muse, mutect2
- FAM47C | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.996); catalogued as COSV63723806; called by muse, mutect2, varscan2
- FAT1 | c.11704C>G p.Q3902E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.42); catalogued as COSV71672040, COSV71673132; called by muse, mutect2
- FKBPL | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 48/489 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV64322305; called by muse, mutect2
- FREM1 | c.5915C>G p.S1972C | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV66518092; called by muse, mutect2, varscan2
- FRMPD4 | c.1360A>T p.K454* | Nonsense Mutation (SNP) | VAF 33/148 reads (22%) | catalogued as COSV101044261; called by muse, mutect2, varscan2
- FRYL | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.841); catalogued as COSV51940055; called by muse, mutect2, varscan2
- FYB2 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.536); catalogued as COSV100599713, COSV100599848; called by muse, mutect2
- GDAP1 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55184898, COSV55186048, COSV55186438; called by muse, mutect2, varscan2
- GGN | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs756822630, COSV53056011; called by muse, mutect2, varscan2
- GIMAP6 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 66/390 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); catalogued as COSV61032535; called by muse, varscan2
- GLUL | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV59381638; called by muse, mutect2, varscan2
- GNE | c.102G>C p.K34N (on ENST00000396594 / NM_001128227.3; = p.K3N on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV64951259; called by muse, mutect2, varscan2
- GPM6A | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54532790, COSV54556173; called by muse, mutect2, varscan2
- HAPLN2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs1394537071, COSV99661056; called by muse, mutect2
- HAUS3 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV54723722, COSV99704426; called by muse, mutect2, varscan2
- HAUS3 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV54721808, COSV99704165; called by muse, mutect2, varscan2
- HK3 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV52837000; called by muse, mutect2, varscan2
- HRNR | c.6281G>C p.S2094T | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs374071881; called by muse, varscan2
- HSP90B1 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55354104; called by muse, mutect2
- HSPB2 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57051259; called by muse, mutect2, varscan2
- IGHV1-46 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.174); catalogued as rs782232985; called by muse, mutect2, varscan2
- IL17A | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as rs1336318401, COSV60683916, COSV60684793; called by muse, mutect2, varscan2
- IPO4 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as rs751437225, COSV55778239; called by muse, mutect2, varscan2
- ITPR2 | c.5704G>A p.E1902K | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV67264919; called by muse, mutect2, varscan2
- KDM1B | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV52808617; called by muse, mutect2, varscan2
- KLHL5 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54671602; called by muse, mutect2, varscan2
- KMT2A | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); catalogued as COSV63282189; called by muse, varscan2
- KMT2A | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as COSV63282196; called by muse, varscan2
- KRTAP6-2 | c.64G>C p.G22R | Missense Mutation (SNP) | VAF 21/89 reads (24%) | PolyPhen probably damaging (0.995); catalogued as COSV58181925, COSV58181997; called by muse, mutect2, varscan2
- LAMB1 | c.4672G>C p.E1558Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as rs1329661475, COSV55961725; called by muse, mutect2, varscan2
- LAX1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs753768323, COSV65848812; called by muse, mutect2, varscan2
- LHFPL3 | c.452C>G p.S151* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV101309034; called by muse, mutect2
- MAGEE2 | c.1402G>T p.G468C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64897304; called by muse, mutect2, varscan2
- MAK | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57564160; called by muse, mutect2, varscan2
- MAP3K6 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV62887210; called by muse, mutect2, varscan2
- MARCHF6 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV56878833; called by muse, mutect2, varscan2
- MCMBP | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV63508519; called by muse, mutect2, varscan2
- METTL14 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.801); catalogued as COSV66310226; called by muse, mutect2, varscan2
- MKI67 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV64072644, COSV64073756; called by muse, mutect2, varscan2
- MLNR | c.1080G>C p.K360N | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs201812411, COSV54531721; called by muse, mutect2, varscan2
- MMRN1 | c.175C>G p.R59G | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV53333838, COSV53341468; called by muse, mutect2, varscan2
- MRPL19 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs776561600, COSV100718502, COSV62566481; called by muse, mutect2, varscan2
- MTFR1 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV50951093; called by mutect2, varscan2
- NHS | c.2938C>T p.P980S | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370808802, COSV66271473; called by muse, mutect2, varscan2
- NUP210 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54402593; called by muse, mutect2
- OR11G2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV62131806, COSV62133077; called by muse, mutect2, varscan2
- OR5K3 | c.638T>C p.L213S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV67349686; called by muse, mutect2, varscan2
- OR8D4 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.057); catalogued as COSV58429515; called by muse, mutect2, varscan2
- PACSIN3 | c.594G>C p.E198D | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV54065199; called by muse, mutect2, varscan2
- PADI4 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100966952; called by muse, mutect2, varscan2
- PCK1 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV60126219, COSV60126822, COSV60128980; called by muse, mutect2, varscan2
- PDE11A | c.54C>A p.H18Q | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV53686611; called by muse, mutect2, varscan2
- PDE3A | c.3412A>T p.K1138* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100762898; called by muse, mutect2, varscan2
- PGR | c.2747A>G p.Q916R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54796542; called by muse, mutect2, varscan2
- PHF23 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.829); catalogued as COSV50034667; called by muse, mutect2, varscan2
- PHLDB1 | c.2164C>G p.Q722E | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV61876480; called by muse, mutect2, varscan2
- PIK3R3 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53104438, COSV53109544; called by muse, mutect2, varscan2
- POLE | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57674516, COSV57680050; called by muse, mutect2, varscan2
- POLI | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV54187780; called by muse, mutect2, varscan2
- PREX2 | c.4360G>C p.D1454H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV55751672; called by muse, mutect2, varscan2
- PRKAA1 | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as COSV62628988; called by muse, mutect2, varscan2
- PROSER1 | c.1100C>G p.S367* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV100613100; called by muse, mutect2, varscan2
- RERE | c.4584G>C p.Q1528H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100557485; called by muse, mutect2
- RGS10 | c.475G>C p.D159H (on ENST00000369101; = p.D153H on NM_002925.3) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs778481186, COSV64861466; called by muse, mutect2, varscan2
- RNF168 | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV58836764; called by muse, mutect2, varscan2
- RUFY2 | c.1378C>T p.L460F | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV56258607; called by muse, mutect2, varscan2
- RUNX3 | c.957G>T p.Q319H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV58242527; called by muse, mutect2, varscan2
- RYR2 | c.5905C>A p.P1969T | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100773189; called by muse, mutect2
- SH3KBP1 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV65646128; called by muse, mutect2, varscan2
- SIPA1 | c.1305C>G p.I435M | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV101255780, COSV67745439; called by muse, mutect2, varscan2
- SKIL | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52058333; called by muse, mutect2, varscan2
- SLC12A9 | c.997T>G p.Y333D | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51931364; called by muse, mutect2, varscan2
- SLC18A3 | c.1244C>G p.S415* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100339963, COSV100341047; called by muse, mutect2, varscan2
- SLC22A2 | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as COSV65265656; called by muse, mutect2, varscan2
- SMARCA5 | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV51642338; called by muse, mutect2, varscan2
- SNTB1 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV67324561; called by muse, mutect2, varscan2
- SOX9 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV55422326; called by muse, mutect2, varscan2
- SPAG17 | c.2960C>T p.S987L | Missense Mutation (SNP) | VAF 82/347 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60453226; called by muse, mutect2, varscan2
- SPATA5 | c.1988G>C p.G663A | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56771986, COSV99916372; called by muse, mutect2, varscan2
- SPIN1 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV65498624, COSV65499762; called by muse, mutect2, varscan2
- SRGN | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV54344173; called by muse, mutect2, varscan2
- STAG1 | c.592T>C p.Y198H | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs769899036, COSV52601935; called by muse, mutect2, varscan2
- STRADA | c.660G>C p.M220I (on ENST00000336174 / NM_001363786.1; = p.M183I on NM_153335.6) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as COSV55561527; called by muse, mutect2, varscan2
- SVIL | c.2128G>T p.E710* (on ENST00000355867 / NM_021738.3; = p.E316* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100881607; called by muse, mutect2, varscan2
- TAB2 | c.1639C>T p.L547F | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53851116; called by muse, mutect2, varscan2
- TENM1 | c.7093G>C p.D2365H | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64425453, COSV64440317; called by muse, mutect2, varscan2
- TFRC | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.613); catalogued as COSV64053855; called by muse, mutect2, varscan2
- THRAP3 | c.2269dup p.T757Nfs*6 | Frame Shift Ins (INS) | VAF 33/115 reads (29%) | catalogued as rs1443424346; called by mutect2, pindel, varscan2
- TP63 | c.1723C>G p.Q575E | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.81); catalogued as COSV53196890, COSV53197182; called by muse, mutect2, varscan2
- TP73 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs749787981, COSV60698569; called by muse, mutect2, varscan2
- TRAPPC10 | c.2080A>G p.I694V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV52375498; called by muse, mutect2, varscan2
- TRIM42 | c.654C>A p.Y218* | Nonsense Mutation (SNP) | VAF 15/150 reads (10%) | catalogued as COSV99648932; called by muse, mutect2
- TRIML2 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58714610; called by muse, mutect2
- TTC3 | c.3344C>G p.S1115C | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61285980; called by muse, mutect2, varscan2
- UBA5 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV53904000; called by muse, mutect2, varscan2
- UBA52 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV55889008; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as COSV51952822; called by muse, mutect2, varscan2
- USH2A | c.8780G>A p.R2927K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as rs936841573, COSV56329489; called by muse, mutect2, varscan2
- USP14 | c.160A>T p.K54* | Nonsense Mutation (SNP) | VAF 10/81 reads (12%) | catalogued as COSV55281734, COSV99864503; called by muse, mutect2, varscan2
- USP9X | c.4442G>A p.G1481E | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV61066222; called by muse, mutect2, varscan2
- VAC14 | c.595-1G>T p.X199_splice | Splice Site (SNP) | VAF 17/88 reads (19%) | catalogued as COSV55751140; called by muse, mutect2, varscan2
- VCAM1 | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs746155083, COSV54117847; called by muse, mutect2, varscan2
- VLDLR | c.2537C>A p.S846Y | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV66077092; called by muse, mutect2, varscan2
- WNK1 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100268855; called by muse, mutect2, varscan2
- XKR4 | c.835C>G p.R279G | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV100533831, COSV59299905, COSV59312309; called by muse, mutect2, varscan2
- ZDHHC21 | c.738C>G p.F246L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.827); catalogued as COSV66612218; called by muse, mutect2, varscan2
- ZFP69 | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65528344; called by muse, mutect2, varscan2
- ZFYVE21 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.588); catalogued as rs1331941041, COSV53694306; called by muse, mutect2
- ZNF337 | c.1185G>C p.Q395H | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53320244; called by muse, mutect2, varscan2
- ZNF382 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.926); catalogued as COSV53086194; called by muse, mutect2, varscan2
- ZNF521 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100831817, COSV64122649; called by muse, mutect2, varscan2
- ZNF578 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as COSV69735962; called by muse, mutect2, varscan2
- ZNF585A | c.622C>T p.H208Y (on ENST00000292841 / NM_001288800.2; = p.H153Y on NM_152655.3) | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53061761; called by muse, mutect2, varscan2
- ZNF791 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as rs371205406, COSV100589171; called by muse, mutect2
- ZNF804A | c.2408T>G p.V803G | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100170547; called by muse, mutect2
- EPG5 | c.3957T>G p.Y1319* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- GIMAP6 | c.182_186del p.L61Qfs*7 | Frame Shift Del (DEL) | VAF 44/366 reads (12%) | called by pindel, varscan2
- SZT2 | c.3241del p.H1081Mfs*23 (on ENST00000634258 / NM_001365999.1; = p.H1024Mfs*23 on NM_015284.4) | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- ACE2 | c.27C>G p.L9= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV53023720, COSV99382573; called by muse, mutect2, varscan2
- ACHE | c.393C>T p.N131= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as rs771459906, COSV53815186; called by muse, mutect2, varscan2
- ADCY1 | c.2379C>G p.L793= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs148089389, COSV52039096; called by muse, mutect2, varscan2
- ADGRG2 | c.1884G>A p.L628= (on ENST00000379869 / NM_001079858.3; = p.L625= on NM_005756.4) | Silent (SNP) | VAF 97/327 reads (30%) | catalogued as COSV61337571; called by muse, mutect2, varscan2
- AGL | c.798C>T p.Y266= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs1011395459, COSV54048353; called by muse, mutect2
- AHNAK | c.12630G>A p.V4210= | Silent (SNP) | VAF 64/493 reads (13%) | catalogued as rs148486975; called by muse, mutect2, varscan2
- ANO7 | c.2334C>T p.I778= (on ENST00000274979; = p.I724= on NM_001370694.2) | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99239638; called by muse, mutect2, varscan2
- ANO9 | c.1098C>T p.A366= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs755720090, COSV60448248; called by muse, mutect2, varscan2
- ASB10 | c.940C>T p.L314= (on ENST00000420175 / NM_001142459.2; = p.L299= on NM_080871.4) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV51994283; called by muse, mutect2, varscan2
- ASB10 | c.939C>T p.L313= (on ENST00000420175 / NM_001142459.2; = p.L298= on NM_080871.4) | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs778152740, COSV51994311; called by muse, mutect2, varscan2
- ATF4 | c.21G>C p.L7= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV57477634; called by muse, mutect2, varscan2
- CAD | c.5337G>A p.V1779= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV53023771; called by muse, mutect2, varscan2
- CAMTA1 | c.3900C>G p.L1300= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV57882747; called by muse, mutect2, varscan2
- CCDC27 | c.774C>G p.L258= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV53898474; called by muse, mutect2, varscan2
- CLASP1 | c.1200G>C p.G400= | Silent (SNP) | VAF 84/235 reads (36%) | catalogued as COSV55314376; called by muse, mutect2, varscan2
- CLCNKA | c.558G>A p.T186= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV100510348, COSV58890420; called by muse, mutect2, varscan2
- CLDN17 | c.204C>T p.S68= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs779880091, COSV54522253; called by muse, mutect2, varscan2
- EEA1 | c.1746G>A p.E582= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as rs771808148, COSV59282766; called by muse, varscan2
- EPS8L2 | c.822G>A p.Q274= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV59346785, COSV59348887; called by muse, mutect2, varscan2
- FHL2 | c.792C>T p.L264= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV59078798; called by muse, mutect2, varscan2
- FNDC1 | c.5442G>A p.L1814= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV51931101; called by muse, mutect2, varscan2
- GABRA1 | c.1284G>A p.P428= | Silent (SNP) | VAF 44/155 reads (28%) | catalogued as rs74873701, COSV50098953, COSV99196274; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- GCNT4 | c.738C>G p.L246= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV59280446; called by muse, mutect2, varscan2
- GP5 | c.1149C>T p.F383= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100541057; called by muse, mutect2
- GRHL2 | c.423C>T p.I141= | Silent (SNP) | VAF 28/220 reads (13%) | catalogued as COSV52544723; called by muse, mutect2, varscan2
- GTPBP2 | c.276G>A p.R92= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs752570862, COSV61075640; called by muse, mutect2, varscan2
- H1-4 | c.63G>A p.K21= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as rs201889498, COSV56799895; called by muse, mutect2, varscan2
- HEATR1 | c.123G>A p.R41= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as rs759899226, COSV63979334; called by muse, mutect2
- HEATR5A | c.2091C>T p.L697= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV66338576; called by muse, mutect2, varscan2
- HK1 | c.531G>A p.A177= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs370998274; called by muse, mutect2, varscan2
- HS3ST3A1 | c.642G>A p.E214= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs878952769, COSV52372883; called by muse, mutect2, varscan2
- HS3ST3B1 | c.597G>A p.E199= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100714598; called by muse, mutect2, varscan2
- HSPG2 | c.7845C>T p.V2615= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV65969089; called by muse, mutect2, varscan2
- JSRP1 | c.870G>A p.P290= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV55553576; called by muse, mutect2, varscan2
- KCNC4 | c.1674C>T p.L558= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV63925058; called by muse, mutect2, varscan2
- KCNH8 | c.3297G>C p.V1099= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100111165; called by muse, mutect2
- LAMA4 | c.4017C>T p.T1339= (on ENST00000230538 / NM_001105206.3; = p.T1332= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV57892173; called by muse, mutect2, varscan2
- LAT2 | c.510G>C p.L170= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV51920555; called by muse, mutect2, varscan2
- LHCGR | c.1722C>T p.L574= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as COSV54292768; called by muse, mutect2, varscan2
- LZTR1 | c.2130C>T p.I710= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as rs149449207; called by muse, mutect2, varscan2
- MRAS | c.561G>A p.K187= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV56670383, COSV56671991; called by muse, mutect2, varscan2
- NCOR1 | c.5184G>A p.R1728= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as COSV51961570; called by muse, mutect2, varscan2
- NCOR1 | c.3198G>A p.L1066= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV51961596, COSV51983983; called by muse, mutect2, varscan2
- NFXL1 | c.816C>A p.L272= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV61198056, COSV61199358; called by muse, mutect2, varscan2
- NHS | c.2250G>A p.A750= | Silent (SNP) | VAF 17/198 reads (9%) | catalogued as rs758417770, COSV101196877, COSV66271468; called by muse, mutect2
- NYNRIN | c.2541G>A p.V847= | Silent (SNP) | VAF 46/197 reads (23%) | catalogued as COSV66841197; called by muse, mutect2, varscan2
- OR5B2 | c.825C>T p.F275= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV56907561; called by muse, mutect2, varscan2
- PEX1 | c.3309C>T p.G1103= | Silent (SNP) | VAF 33/182 reads (18%) | catalogued as COSV50394730; called by muse, mutect2, varscan2
- PIP5K1C | c.366C>A p.L122= | Silent (SNP) | VAF 47/156 reads (30%) | catalogued as COSV58950195; called by muse, mutect2, varscan2
- PKHD1L1 | c.36C>T p.L12= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV101006957; called by muse, mutect2
- PLD1 | c.1644G>A p.L548= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV60565447, COSV60566539; called by muse, mutect2, varscan2
- PPM1A | c.816C>T p.V272= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as rs775726793, COSV57785577; called by muse, mutect2
- PTX4 | c.162G>C p.V54= (on ENST00000447419 / NM_001328608.2; = p.V49= on NM_001013658.1) | Silent (SNP) | VAF 34/166 reads (20%) | catalogued as COSV53514319; called by muse, mutect2, varscan2
- PYGB | c.1737C>G p.L579= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV53815842; called by muse, mutect2, varscan2
- RAG2 | c.1449G>A p.E483= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as rs1441597690, COSV57556455; called by muse, mutect2, varscan2
- RGS9 | c.1563C>T p.I521= | Silent (SNP) | VAF 118/290 reads (41%) | catalogued as COSV52223178; called by muse, mutect2, varscan2
- RYR1 | c.2340C>T p.V780= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV62089321; called by muse, mutect2, varscan2
- RYR2 | c.945A>G p.L315= | Silent (SNP) | VAF 13/150 reads (9%) | catalogued as COSV63663351, COSV63702969; called by muse, mutect2
- SHF | c.387G>A p.E129= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV52049375; called by muse, mutect2, varscan2
- SIGLEC10 | c.1420C>T p.L474= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100219497; called by muse, mutect2
- SLC18A3 | c.924C>T p.L308= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as rs200094927, COSV60320430; called by muse, mutect2, varscan2
- SLC1A7 | c.1338C>G p.L446= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV57011021; called by muse, varscan2
- SLC8A3 | c.1599T>A p.T533= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as COSV100776409; called by muse, mutect2
- SQLE | c.1644C>T p.L548= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV56281146; called by muse, mutect2
- SSUH2 | c.126C>G p.L42= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs774885903, COSV58028952; called by muse, mutect2, varscan2
- TAS2R19 | c.570G>A p.L190= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as COSV66827982; called by muse, mutect2, varscan2
- TEP1 | c.5790C>T p.A1930= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as COSV52988207; called by muse, mutect2, varscan2
- TEP1 | c.3645C>T p.L1215= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99403417; called by muse, mutect2, varscan2
- TMTC4 | c.1413C>T p.F471= (on ENST00000376234 / NM_001350577.2; = p.F490= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 39/254 reads (15%) | catalogued as COSV60891365; called by muse, mutect2, varscan2
- TRIM33 | c.1245C>T p.F415= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV61820848; called by muse, mutect2, varscan2
- WDFY3 | c.10580G>A p.*3527= | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as COSV99886060; called by muse, mutect2, varscan2
- WEE1 | c.954G>A p.K318= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as rs1028134006, COSV55196327; called by muse, mutect2, varscan2
- YLPM1 | c.438C>T p.P146= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs753694448, COSV53106371; called by muse, mutect2
- ZNF337 | c.765G>A p.Q255= | Silent (SNP) | VAF 46/185 reads (25%) | catalogued as COSV53320253; called by muse, mutect2, varscan2
- ZNF43 | c.456G>C p.V152= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV61682800; called by muse, mutect2, varscan2
- ZNF585A | c.1683G>A p.Q561= (on ENST00000292841 / NM_001288800.2; = p.Q506= on NM_152655.3) | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV99493683; called by muse, mutect2, varscan2
- DCHS2 | n.2582G>T | RNA (SNP) | VAF 17/120 reads (14%) | catalogued as COSV59718640; called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.124C>T | RNA (SNP) | VAF 34/159 reads (21%) | called by muse, mutect2, varscan2
- VPS50 | c.942+37C>G | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99298590; called by muse, mutect2
